CCDI case PBCFKK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/82e3a0f3-4565-4d45-bc21-6d8fff9d5a41

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 6.3 years (2,288 days).

Biospecimens (3 samples)
- Samples 0DR1XE, 0DR20L (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR1YP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
